Somatic mutation profile of tumor specimen C3L-02665-01 (aliquot CPT0192540007) from CPTAC case C3L-02665, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.1 years (18,659 days).
Specimen C3L-02665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d08b289-d601-41fd-9646-891e48ab6780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02665-31 (Blood Derived Normal), aliquot CPT0192700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34731ec5-deb1-4f6c-9f1e-87367332ea63

The open-access MAF lists 699 somatic variants for this specimen: 483 protein-altering or splice-affecting, 127 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 407, Silent 127, Nonsense Mutation 35, Intron 34, Frame Shift Del 18, 5'UTR 16, RNA 16, 3'UTR 15, Splice Region 10, Splice Site 10, 3'Flank 4, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 121/288 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSS2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 48/220 reads (22%) | catalogued as rs1188090775; called by muse, mutect2, varscan2
- AHRR | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 232/636 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV57088478; called by muse, mutect2, varscan2
- ALG3 | c.297G>T p.V99= | Splice Region (SNP) | VAF 13/100 reads (13%) | catalogued as rs1330024946; called by muse, mutect2, varscan2
- ALPK2 | c.3310G>C p.D1104H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs577596399; called by muse, mutect2, varscan2
- AMER3 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs746960728, COSV58465636; called by muse, mutect2, varscan2
- AMPH | c.1862C>A p.P621H | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57750916; called by muse, mutect2, varscan2
- ANK1 | c.4700A>T p.Q1567L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.105); catalogued as COSV55899247; called by muse, mutect2, varscan2
- ANKUB1 | c.1288dup p.I430Nfs*6 | Frame Shift Ins (INS) | VAF 28/178 reads (16%) | catalogued as rs1314304040; called by mutect2, varscan2
- ARFGEF2 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100904252; called by muse, mutect2, varscan2
- ASXL3 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52468216; called by muse, mutect2, varscan2
- BCL11B | c.965G>T p.R322L (on ENST00000357195 / NM_001282237.2; = p.R251L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV61738759; called by muse, mutect2, varscan2
- BPIFB3 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100972435; called by muse, mutect2, varscan2
- C12orf50 | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as rs1312016919, COSV53895829; called by muse, mutect2, varscan2
- C1orf43 | c.547del p.L183* (on ENST00000368521 / NM_001297718.2; = p.L149* on NM_015449.4) | Frame Shift Del (DEL) | VAF 93/392 reads (24%) | catalogued as rs750473329; called by mutect2, pindel, varscan2
- C6orf15 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs199527614; called by muse, mutect2, varscan2
- CACNA1A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64201789; called by muse, mutect2, varscan2
- CADM2 | c.295G>A p.E99K (on ENST00000407528 / NM_001167674.2; = p.E101K on NM_153184.4) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV67374908; called by muse, mutect2
- CAST | c.21+5G>C | Splice Region (SNP) | VAF 62/179 reads (35%) | catalogued as COSV100352583; called by muse, mutect2, varscan2
- CATSPERD | c.1690T>A p.F564I | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs749839049; called by muse, mutect2, varscan2
- CBX6 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777300626; called by muse, mutect2, varscan2
- CCDC38 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.271); catalogued as rs201941109; called by muse, mutect2, varscan2
- CCNF | c.594+1G>C p.X198_splice | Splice Site (SNP) | VAF 47/284 reads (17%) | catalogued as COSV53543849; called by muse, mutect2, varscan2
- CDCP2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 87/452 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220852840; called by muse, mutect2, varscan2
- CEP128 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV55390708; called by muse, mutect2, varscan2
- CFAP58 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV57212162; called by muse, mutect2, varscan2
- COL24A1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV65308025; called by muse, mutect2, varscan2
- COL5A2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 154/414 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1455355520; called by muse, mutect2, varscan2
- COL6A1 | c.1660del p.D554Tfs*48 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | catalogued as rs1569518775; called by mutect2, pindel, varscan2
- COL6A6 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV62026199; called by muse, mutect2, varscan2
- CORO2B | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763566862; called by muse, mutect2
- CUL3 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 53/146 reads (36%) | catalogued as COSV100023589; called by muse, mutect2, varscan2
- CXorf58 | c.870A>T p.Q290H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV64858285; called by muse, mutect2, varscan2
- CYP46A1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.645); catalogued as COSV55895568; called by muse, mutect2, varscan2
- DAAM1 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.815); catalogued as COSV62835497; called by muse, mutect2, varscan2
- DCAF5 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs750737328; called by muse, mutect2, varscan2
- DIDO1 | c.5854G>T p.A1952S | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV56614092; called by muse, mutect2, varscan2
- DLGAP3 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); catalogued as COSV52393377; called by muse, mutect2, varscan2
- DNAH7 | c.7728G>C p.K2576N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV56750734; called by muse, mutect2
- DOCK10 | c.4597A>G p.T1533A | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51408540; called by muse, mutect2, varscan2
- DOCK3 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56510465; called by muse, mutect2, varscan2
- EMP2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as COSV63995963; called by muse, mutect2, varscan2
- ESS2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV50082238, COSV99324015; called by muse, varscan2
- FCGBP | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs753515237; called by muse, mutect2, varscan2
- FCRL4 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as COSV99620362; called by muse, mutect2, varscan2
- FER1L6 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV67553716; called by muse, mutect2, varscan2
- FLNC | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 215/641 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57957886; called by muse, mutect2, varscan2
- FMN1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998850427; called by muse, mutect2, varscan2
- FMN2 | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV60431541; called by muse, mutect2, varscan2
- FRYL | c.5957G>A p.G1986E | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs777537020; called by muse, mutect2, varscan2
- GABRA4 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320956125; called by muse, mutect2, varscan2
- GABRG1 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.981); catalogued as rs746510226, COSV54950313; called by muse, mutect2, varscan2
- GANC | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | PolyPhen probably damaging (0.996); catalogued as COSV58812405; called by muse, mutect2, varscan2
- GJA9 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs901830756, COSV62532697; called by muse, mutect2, varscan2
- GRIK3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66135379; called by muse, mutect2, varscan2
- GSDME | c.333C>G p.S111R | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as rs778619140; called by muse, mutect2, varscan2
- HNRNPCL1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs746456942; called by muse, mutect2, varscan2
- IGF2BP2 | c.1687G>T p.G563W | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60482674; called by mutect2, varscan2
- IGKV3-11 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 133/515 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as rs751223063; called by muse, mutect2, varscan2
- ITGA8 | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1409925308; called by muse, mutect2, varscan2
- JHY | c.2055G>T p.K685N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57076911; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2293+4A>G | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as rs1402893754; called by muse, mutect2, varscan2
- KEAP1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50646098; called by muse, mutect2, varscan2
- KNDC1 | c.2268G>T p.Q756H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58839704; called by muse, mutect2, varscan2
- LAMB4 | c.1975C>A p.Q659K | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99063920; called by muse, mutect2, varscan2
- LCE2B | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 152/512 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1228200956, COSV64227539; called by muse, mutect2, varscan2
- LGALS14 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 142/400 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs763261682; called by muse, mutect2, varscan2
- LRRC3C | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as rs570722308; called by muse, mutect2, varscan2
- MAGEC1 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs771616249; called by muse, mutect2, varscan2
- MAGEL2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated, low confidence (0.07); catalogued as COSV58568574, COSV58568736; called by muse, mutect2, varscan2
- MCHR2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV56003204; called by muse, mutect2
- MDGA2 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62087894; called by muse, mutect2, varscan2
- MKRN3 | c.1040G>T p.W347L | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58809942; called by muse, mutect2, varscan2
- MKRN3 | c.1041G>T p.W347C | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58810208; called by muse, mutect2, varscan2
- MSLNL | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs745418221, COSV53500196; called by muse, mutect2, varscan2
- MXRA5 | c.8017C>G p.L2673V | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs749719579; called by muse, mutect2, varscan2
- MYO16 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768065230, COSV51779591, COSV99193431; called by muse, mutect2, varscan2
- NAGPA | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 67/265 reads (25%) | PolyPhen benign (0.223); catalogued as rs760685655; called by muse, mutect2, varscan2
- NCKAP5 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 62/231 reads (27%) | catalogued as COSV100491201; called by muse, mutect2, varscan2
- NDUFS4 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 213/722 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.098); catalogued as rs752987035; called by muse, mutect2, varscan2
- NETO2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs750819621; called by muse, mutect2, varscan2
- NEU4 | c.776C>T p.S259F (on ENST00000391969 / NM_001167602.3; = p.S271F on NM_080741.4) | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.115); catalogued as rs907177436; called by muse, mutect2, varscan2
- NKX3-2 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.07); catalogued as COSV66711776; called by muse, mutect2, varscan2
- NMNAT2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV55084943; called by muse, mutect2, varscan2
- NRDE2 | c.2825G>T p.G942V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV62963996; called by muse, mutect2, varscan2
- OBSCN | c.19574C>T p.T6525M | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746689888, COSV62604113; called by muse, mutect2, varscan2
- OR1C1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV68715983; called by muse, mutect2, varscan2
- OR4K15 | c.26G>C p.C9S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); catalogued as rs1246228561; called by muse, mutect2, varscan2
- OR4M1 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781704263, COSV60063685; called by muse, mutect2, varscan2
- OR6K3 | c.540del p.T181Hfs*21 (on ENST00000368146; = p.T165Hfs*21 on NM_001005327.2) | Frame Shift Del (DEL) | VAF 86/297 reads (29%) | catalogued as COSV100933880; called by mutect2, pindel, varscan2
- OR8B12 | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV60911636; called by muse, mutect2, varscan2
- OTOF | c.5782C>A p.R1928S (on ENST00000272371 / NM_194248.3; = p.R1161S on NM_004802.4) | Missense Mutation (SNP) | VAF 87/577 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV55501759; called by muse, mutect2, varscan2
- PCDHA13 | c.1936C>A p.R646S | Missense Mutation (SNP) | VAF 138/361 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.169); catalogued as rs1410511984; called by muse, mutect2, varscan2
- PCDHB8 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 173/520 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV50818420; called by muse, mutect2, varscan2
- PCLO | c.12331G>C p.E4111Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100435816; called by muse, mutect2, varscan2
- PFKM | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs970220488, COSV56655991; called by muse, mutect2
- PIEZO2 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100123976; called by muse, mutect2, varscan2
- PKHD1L1 | c.8518G>C p.A2840P | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101005921; called by muse, mutect2, varscan2
- PLBD2 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs559824346; called by muse, mutect2, varscan2
- PLCB4 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV53802842; called by muse, mutect2, varscan2
- PLCL2 | c.2201G>T p.R734M (on ENST00000615277 / NM_001144382.2; = p.R608M on NM_015184.5) | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196539; called by muse, mutect2, varscan2
- PLP1 | c.370A>T p.R124W | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as CD1311160; called by muse, mutect2, varscan2
- POMC | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1323038048, COSV99256837; called by muse, mutect2, varscan2
- POTEA | c.1376C>G p.S459* (on ENST00000519951 / NM_001005365.2; = p.S413* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as rs370141349; called by muse, mutect2
- PPFIA4 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99829915; called by muse, mutect2, varscan2
- PROS1 | c.234G>T p.T78= | Splice Region (SNP) | VAF 37/275 reads (13%) | catalogued as COSV62400020; called by muse, mutect2, varscan2
- PTPN9 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144012; called by muse, mutect2, varscan2
- R3HDM1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as rs1463551193; called by muse, mutect2, varscan2
- RIC3 | c.628G>A p.E210K (on ENST00000309737 / NM_001206671.4; = p.E209K on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58305319; called by muse, mutect2, varscan2
- RSAD2 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761701524, COSV101149826; called by muse, mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2, varscan2
- RYR2 | c.6637G>T p.A2213S | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.617); catalogued as CM1411478, COSV63662555, COSV63709863; called by muse, mutect2, varscan2
- SFRP1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV55173682; called by muse, mutect2, varscan2
- SGSH | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs201061563; called by muse, mutect2, varscan2
- SLC45A4 | c.1621G>C p.D541H (on ENST00000517878 / NM_001286646.2; = p.D490H on NM_001080431.2) | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99199773; called by muse, mutect2, varscan2
- SLC49A4 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 198/680 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1379255865; called by muse, mutect2, varscan2
- SLIT1 | c.1083G>T p.S361= | Splice Region (SNP) | VAF 94/218 reads (43%) | catalogued as rs756480506; called by muse, mutect2, varscan2
- SOWAHB | c.2159G>A p.W720* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as rs1261987322; called by muse, mutect2, varscan2
- SOX6 | c.1569C>A p.D523E (on ENST00000528429 / NM_001145819.2; = p.D496E on NM_017508.3) | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs369713124; called by muse, mutect2, varscan2
- SPRING1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV54338923; called by muse, mutect2, varscan2
- SSH1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100425501; called by muse, varscan2
- ST6GALNAC5 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 33/140 reads (24%) | PolyPhen probably damaging (0.998); catalogued as COSV59564102; called by muse, mutect2, varscan2
- STC1 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs186260860; called by muse, mutect2, varscan2
- TAX1BP1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55290897; called by muse, mutect2, varscan2
- TCHH | c.3928C>A p.R1310S | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV64274999; called by muse, mutect2, varscan2
- TENM3 | c.7802G>C p.G2601A | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV99073216; called by muse, mutect2, varscan2
- TLE3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV58167025, COSV58174440; called by muse, mutect2, varscan2
- TMEM214 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV53192640; called by muse, mutect2, varscan2
- TMEM41B | c.536del p.L179Qfs*6 | Frame Shift Del (DEL) | VAF 18/191 reads (9%) | catalogued as COSV100215880; called by mutect2, pindel*
- TMEM44 | c.805G>T p.A269S (on ENST00000392432 / NM_001166305.2; = p.A222S on NM_138399.5) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.523); catalogued as rs1274691012; called by muse, mutect2, varscan2
- TOLLIP | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1172883214; called by muse, mutect2, varscan2
- UNK | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53139052; called by muse, mutect2, varscan2
- UPF3B | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52232212; called by muse, mutect2, varscan2
- USH2A | c.10478G>C p.R3493T | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201182885; called by muse, mutect2, varscan2
- USH2A | c.5365C>A p.L1789I | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV56370263; called by muse, mutect2, varscan2
- USP26 | c.1958C>A p.P653Q | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs148955505, COSV63708773; called by muse, mutect2, varscan2
- UTP20 | c.3869A>G p.E1290G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs916319852; called by muse, varscan2
- ZIM3 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54143187, COSV99518481; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 86/662 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.23); catalogued as rs754830739; called by muse, mutect2, varscan2
- ZNF407 | c.1821G>T p.M607I | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV55254122; called by muse, mutect2, varscan2
- ZNRF3 | c.1447G>T p.E483* (on ENST00000544604 / NM_001206998.2; = p.E383* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 86/180 reads (48%) | catalogued as COSV100238095; called by muse, mutect2, varscan2
- ZSCAN4 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV56593432; called by muse, mutect2, varscan2
- ABAT | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 131/494 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ABCA13 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 43/233 reads (18%) | called by muse, mutect2, varscan2
- ABCC12 | c.3691G>T p.E1231* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- ABI3BP | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ACBD4 | c.19A>T p.S7C | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACSM2A | c.1457C>A p.P486H (on ENST00000219054; = p.P407H on NM_001308169.2) | Missense Mutation (SNP) | VAF 43/455 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ACTR1B | c.425A>C p.Q142P | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM19 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS10 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ADAMTS20 | c.2716C>A p.L906I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ADAMTS4 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2
- ADGRA1 | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ADGRA1 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADRA2A | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- AHCTF1 | c.3544G>T p.V1182L (on ENST00000366508; = p.V1156L on NM_015446.5) | Missense Mutation (SNP) | VAF 55/385 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP8 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AKT2 | c.840C>A p.N280K | Missense Mutation (SNP) | VAF 82/668 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AL159163.1 | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- AMIGO2 | c.910del p.E304Kfs*3 | Frame Shift Del (DEL) | VAF 59/320 reads (18%) | called by mutect2, pindel, varscan2
- ANK2 | c.3894G>T p.R1298S | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO6 | c.2671G>T p.G891W | Missense Mutation (SNP) | VAF 83/382 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- AP1G1 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APAF1 | c.2840A>C p.Q947P (on ENST00000551964 / NM_181861.2; = p.Q893P on NM_001160.3) | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- APCDD1L | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP2 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AQP12B | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 351/696 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ARFGEF2 | c.1804G>C p.G602R | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARHGAP15 | c.1085T>A p.L362Q | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1B | c.2617G>T p.G873W | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMCX2 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 110/171 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ASTL | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ASXL3 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRNL1 | c.2060A>C p.D687A | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AXIN1 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL11A | c.1249G>T p.G417C (on ENST00000335712 / NM_001365609.1; = p.G451C on NM_018014.4) | Missense Mutation (SNP) | VAF 62/589 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BGN | c.177C>G p.Y59* | Nonsense Mutation (SNP) | VAF 57/101 reads (56%) | called by muse, mutect2, varscan2
- BOD1L2 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- C12orf56 | c.1822C>G p.Q608E (on ENST00000543942 / NM_001170633.2; = p.Q448E on NM_001099676.3) | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C15orf39 | c.3029T>A p.L1010Q | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C8B | c.960A>T p.R320S | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- C9 | c.1537T>C p.C513R | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1D | c.4000del p.E1334Kfs*24 (on ENST00000350061 / NM_001128840.3; = p.E1354Kfs*24 on NM_000720.4) | Frame Shift Del (DEL) | VAF 64/312 reads (21%) | called by mutect2, varscan2
- CAMKK2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CAP2 | c.277T>G p.S93A | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CAPN10 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CAPSL | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CASD1 | c.2110G>C p.G704R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASS4 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CCDC180 | c.3235A>T p.T1079S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CCT3 | c.31+2T>C p.X11_splice | Splice Site (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- CD177 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH2 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDKN1A | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDKN2A | c.119_150+8del p.X40_splice | Splice Site (DEL) | VAF 62/254 reads (24%) | called by mutect2, pindel
- CELSR3 | c.3028T>G p.F1010V | Missense Mutation (SNP) | VAF 72/400 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP47 | c.8383T>C p.W2795R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CHD6 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CNGB1 | c.2870T>A p.V957D | Missense Mutation (SNP) | VAF 118/813 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CNTN1 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- COL15A1 | c.3831C>A p.N1277K | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL17A1 | c.572T>A p.V191E | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- COL22A1 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL24A1 | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A3 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 171/442 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPNE4 | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRB1 | c.2842+1G>T p.X948_splice | Splice Site (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- CSDE1 | c.894del p.F299Lfs*10 (on ENST00000358528 / NM_001007553.3; = p.F268Lfs*10 on NM_007158.6) | Frame Shift Del (DEL) | VAF 39/222 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5804G>C p.C1935S (on ENST00000297405 / NM_001363185.1; = p.C1831S on NM_052900.3) | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CSNK1D | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 142/558 reads (25%) | called by muse, mutect2, varscan2
- CUTC | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- CUX2 | c.1553C>A p.T518K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP3A4 | c.109_110del p.G37Nfs*18 | Frame Shift Del (DEL) | VAF 89/388 reads (23%) | called by mutect2, pindel, varscan2
- CYP8B1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCLK3 | c.1695C>A p.N565K | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DCSTAMP | c.1409C>A p.S470* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- DDX10 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DDX53 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DEFA3 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- DLX1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- DLX6 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.395); called by muse, varscan2
- DNAH10 | c.5879C>T p.S1960F (on ENST00000409039; = p.S1899F on NM_207437.3) | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- DNAH11 | c.4825C>A p.L1609I | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DPYS | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DRD1 | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRP2 | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DZIP3 | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EDA2R | c.419T>A p.V140D | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- EFR3A | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2
- EIF2AK4 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- ENPP7 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 100/620 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVV-2 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- EVC | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FAAP100 | c.1631G>C p.C544S | Missense Mutation (SNP) | VAF 82/582 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FAM47B | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 143/245 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM90A1 | c.126C>T p.L42= | Splice Region (SNP) | VAF 84/442 reads (19%) | called by muse, mutect2, varscan2
- FBXL7 | c.432G>C p.W144C | Missense Mutation (SNP) | VAF 189/664 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FBXO10 | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGFR2 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 177/429 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- FNDC1 | c.4267G>C p.D1423H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FNDC3B | c.1515A>C p.E505D | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOLH1 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXL1 | c.70del p.E24Rfs*15 | Frame Shift Del (DEL) | VAF 53/264 reads (20%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FSIP2 | c.3442C>G p.L1148V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FSIP2 | c.5651C>A p.T1884N | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.13818T>G p.D4606E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GABRB3 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAGE1 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 58/1642 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GBE1 | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GDPD4 | c.1585C>G p.P529A | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GIPC3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GNB5 | c.506A>G p.N169S (on ENST00000261837 / NM_016194.4; = p.N127S on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GRIA2 | c.1840C>G p.P614A | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, varscan2
- GRM3 | c.2360C>G p.P787R | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GRM4 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1960A>T p.I654L | Missense Mutation (SNP) | VAF 49/458 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- GTPBP2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GTSE1 | c.2097G>C p.M699I | Missense Mutation (SNP) | VAF 67/434 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HEATR1 | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- HECW1 | c.3070T>A p.W1024R | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC2 | c.7114G>T p.E2372* | Nonsense Mutation (SNP) | VAF 26/285 reads (9%) | called by muse, mutect2, varscan2
- HRNR | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 173/566 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HSPA6 | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by mutect2, varscan2
- HTD2 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2
- HUS1B | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- IGKV1-39 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); called by mutect2, varscan2
- IGKV1D-33 | c.47G>T p.W16L | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGKV2D-26 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 39/231 reads (17%) | called by muse, mutect2, varscan2
- IGKV3D-7 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 95/448 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- IGSF11 | c.1231C>A p.L411M (on ENST00000393775 / NM_001015887.3; = p.L410M on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- IL18RAP | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IL18RAP | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- INF2 | c.2998A>C p.S1000R | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IQCN | c.1737G>C p.K579N | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ITGA11 | c.1619C>A p.A540D | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ITGAV | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB8 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.179); called by muse, varscan2
- ITGBL1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- JHY | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- KCNV1 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KDM5A | c.3938T>G p.L1313* | Nonsense Mutation (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- KEAP1 | c.1444A>G p.N482D | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KIAA1109 | c.13745A>G p.Q4582R | Missense Mutation (SNP) | VAF 160/295 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KIF13B | c.4153G>C p.V1385L | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF15 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIF1B | c.1345A>T p.S449C (on ENST00000377086 / NM_001365952.1; = p.S403C on NM_015074.3) | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF2B | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KIF5A | c.395A>T p.K132M | Missense Mutation (SNP) | VAF 140/406 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL40 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2D | c.15378C>G p.F5126L | Missense Mutation (SNP) | VAF 117/851 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KRTAP4-2 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 183/495 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LAMA1 | c.1025T>A p.V342D | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LAMB1 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LBP | c.450del p.R151Gfs*28 | Frame Shift Del (DEL) | VAF 41/260 reads (16%) | called by mutect2, pindel, varscan2
- LDHC | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS1 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LGI2 | c.668A>T p.H223L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHCGR | c.1007G>A p.C336Y | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MACF1 | c.21428A>T p.E7143V (on ENST00000372915; = p.E5188V on NM_012090.5) | Missense Mutation (SNP) | VAF 88/260 reads (34%) | called by muse, mutect2, varscan2
- MAGEB6 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 94/130 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI1 | c.2776G>A p.E926K (on ENST00000402939 / NM_001033057.2; = p.E954K on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- MAP3K15 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K7CL | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MEP1B | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MGAM2 | c.3195A>C p.Q1065H | Missense Mutation (SNP) | VAF 78/512 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- MGAM2 | c.3239C>G p.T1080R | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MIDEAS | c.2827G>T p.E943* | Nonsense Mutation (SNP) | VAF 68/334 reads (20%) | called by muse, mutect2, varscan2
- MMP11 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.049); called by muse, mutect2
- MTMR3 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 75/262 reads (29%) | called by mutect2, varscan2
- MUC16 | c.34825A>T p.S11609C | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MUC17 | c.7925C>A p.T2642N | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MYCBP2 | c.5471C>A p.T1824K (on ENST00000357337; = p.T1862K on NM_015057.5) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYH1 | c.2599C>A p.L867M | Missense Mutation (SNP) | VAF 146/385 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MYH7B | c.3487G>A p.A1163T | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- MYH8 | c.3273C>A p.S1091R | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYLK2 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 92/452 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYO16 | c.4471C>G p.P1491A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO1A | c.1006A>T p.M336L | Missense Mutation (SNP) | VAF 151/811 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAALADL1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 50/461 reads (11%) | called by muse, mutect2, varscan2
- NBEAL1 | c.7540G>T p.G2514* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- NBPF1 | c.2365G>C p.V789L | Missense Mutation (SNP) | VAF 75/671 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NBPF11 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 152/838 reads (18%) | called by muse, mutect2, varscan2
- NETO1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NEUROD6 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NF1 | c.7933G>T p.E2645* (on ENST00000358273 / NM_001042492.3; = p.E2624* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 121/313 reads (39%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.482G>T p.W161L | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- NLGN2 | c.1381del p.V461Wfs*75 | Frame Shift Del (DEL) | VAF 49/136 reads (36%) | called by mutect2, pindel, varscan2
- NLRP12 | c.2071C>A p.L691I | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP13 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NLRP3 | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME7 | c.817A>C p.M273L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- NPHP4 | c.3820G>A p.D1274N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NSD2 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NUDT16 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NUP210 | c.3349G>C p.E1117Q | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NXPE4 | c.970A>T p.T324S (on ENST00000375478 / NM_001077639.2; = p.T40S on NM_017678.3) | Missense Mutation (SNP) | VAF 138/393 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OBSCN | c.11707G>T p.E3903* | Nonsense Mutation (SNP) | VAF 185/588 reads (31%) | called by muse, mutect2, varscan2
- OPN5 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- OR2H1 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR2L3 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, varscan2
- OR2L8 | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR4N5 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4X1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2
- OR51B4 | c.384G>C p.R128S | Missense Mutation (SNP) | VAF 117/222 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR52K2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 146/315 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5A2 | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PABPC4 | c.711T>G p.S237R | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PADI6 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PADI6 | c.2030G>T p.C677F | Missense Mutation (SNP) | VAF 66/455 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PANK4 | c.1650G>T p.W550C | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PAOX | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- PASK | c.2282G>T p.C761F | Missense Mutation (SNP) | VAF 189/522 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH18 | c.878T>G p.I293S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PCDH8 | c.1663del p.D555Tfs*40 | Frame Shift Del (DEL) | VAF 55/206 reads (27%) | called by mutect2, pindel*, varscan2
- PCDH8 | c.502G>C p.G168R | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PCDHA11 | c.1274C>A p.T425N | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCLO | c.3575A>T p.D1192V | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- PDCD1 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 87/681 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDE7B | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN4 | c.1321G>C p.A441P (on ENST00000402685 / NM_001164595.2; = p.A183P on NM_013377.4) | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA6 | c.3486G>T p.Q1162H (on ENST00000414982 / NM_001166111.2; = p.Q1114H on NM_006702.5) | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPARGC1A | c.1983G>T p.R661S | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PPP1R21 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 48/501 reads (10%) | called by muse, mutect2
- PPP1R26 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PPP1R37 | c.1886C>G p.S629* | Nonsense Mutation (SNP) | VAF 51/218 reads (23%) | called by muse, mutect2, varscan2
- PPP1R3A | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PPP4R3C | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PROSER1 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PSPH | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRC | c.1483A>T p.M495L | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXDNL | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PZP | c.638_639del p.R213Nfs*16 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, pindel, varscan2
- QSER1 | c.2129A>T p.H710L (on ENST00000399302; = p.H839L on NM_001076786.3) | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RALGAPB | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RBBP6 | c.3658G>T p.G1220* | Nonsense Mutation (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- RBP3 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RCE1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RCVRN | c.477T>A p.F159L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RELCH | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RFPL3 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RGS5 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RNF113B | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RNF123 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- RNF150 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RNF17 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RNF17 | c.2685C>A p.H895Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO1 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RRM2B | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RTL1 | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RYR2 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RYR3 | c.2783A>T p.K928I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SACS | c.13238A>T p.Q4413L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SALL1 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SARDH | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- SCN10A | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- SCN2A | c.4822G>C p.G1608R | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN4A | c.3356A>T p.Y1119F | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SDHC | c.21-1G>T p.X7_splice | Splice Site (SNP) | VAF 13/411 reads (3%) | called by muse, mutect2
- SDS | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SERPINB13 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB7 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETDB1 | c.3669+3G>A | Splice Region (SNP) | VAF 85/468 reads (18%) | called by muse, mutect2, varscan2
- SF3B2 | c.779T>A p.M260K | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2
- SF3B2 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- SHISA7 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 175/372 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SIRPB1 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SKA2 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC22A16 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- SLC22A25 | c.1095G>T p.W365C | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SLC26A11 | c.1522+1G>T p.X508_splice | Splice Site (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- SLC45A1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SLC7A10 | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC8A1 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLITRK2 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLMAP | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 123/1033 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SMG1 | c.7659C>G p.I2553M | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- SMIM8 | n.571G>T | Splice Region (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2
- SNRNP48 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SNTB1 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2
- SORL1 | c.5593C>T p.P1865S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by mutect2, varscan2
- SOX4 | c.1154_1155dup p.S386Tfs*24 | Frame Shift Ins (INS) | VAF 39/271 reads (14%) | called by mutect2, pindel, varscan2
- SPATA18 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SPATA31A6 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 123/495 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SPATA31D1 | c.3312G>T p.Q1104H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SPEF2 | c.3319C>T p.Q1107* | Nonsense Mutation (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- SSH1 | c.634_635del p.S212Lfs*35 | Frame Shift Del (DEL) | VAF 60/237 reads (25%) | called by pindel, varscan2
- SULF2 | c.1321C>A p.R441S | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX2 | c.2002G>T p.G668W | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TCEA1 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- TCF15 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TDG | c.409-1G>C p.X137_splice | Splice Site (SNP) | VAF 47/219 reads (21%) | called by muse, mutect2, varscan2
- TEF | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2
- TEX10 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TGFBRAP1 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TLL1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
- TLL1 | c.2536G>C p.G846R | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- TMEM132B | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM260 | c.162G>T p.G54= | Splice Region (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- TNRC18 | c.8344del p.L2782Cfs*19 | Frame Shift Del (DEL) | VAF 71/587 reads (12%) | called by mutect2, pindel, varscan2
- TP63 | c.993-1G>T p.X331_splice | Splice Site (SNP) | VAF 120/423 reads (28%) | called by muse, mutect2, varscan2
- TPH2 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPP2 | c.2423G>C p.G808A | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TRAJ11 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 21/156 reads (13%) | PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TRBV28 | c.106_134del p.E36Yfs*4 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- TRHDE | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.311); called by muse, varscan2
- TRIM37 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRMT1L | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, varscan2
- TRPC4AP | c.1596-2A>T p.X532_splice | Splice Site (SNP) | VAF 65/229 reads (28%) | called by muse, mutect2, varscan2
- TRPV3 | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTBK1 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TTLL12 | c.1576-4G>A | Splice Region (SNP) | VAF 60/391 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.79816G>A p.V26606I (on ENST00000591111; = p.V19182I on NM_003319.4) | Missense Mutation (SNP) | VAF 56/302 reads (19%) | PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TTN | c.5983del p.E1995Kfs*51 (on ENST00000591111; = p.E1949Kfs*51 on NM_003319.4) | Frame Shift Del (DEL) | VAF 94/305 reads (31%) | called by mutect2, pindel, varscan2
- UCHL5 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UCK1 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- USH2A | c.4934G>C p.G1645A | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- USH2A | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2
- USP32 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP6 | c.2083G>T p.G695W | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VAV1 | c.193dup p.Q65Pfs*9 | Frame Shift Ins (INS) | VAF 41/193 reads (21%) | called by mutect2, pindel, varscan2
- VWA3B | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- WDR7 | c.4064G>T p.R1355M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- WDR87 | c.4109del p.G1370Afs*7 | Frame Shift Del (DEL) | VAF 83/298 reads (28%) | called by mutect2, pindel, varscan2
- WLS | c.334T>G p.F112V | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- WNK4 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- XIRP2 | c.6953C>A p.S2318Y (on ENST00000628543; = p.S2493Y on NM_152381.6) | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- XPO6 | c.2066G>T p.R689L | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- XRCC1 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- YLPM1 | c.1332G>T p.Q444H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZBBX | c.1275-1G>T p.X425_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- ZFPM2 | c.1631T>G p.M544R | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZGRF1 | c.4168G>A p.D1390N | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZHX1 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZMYM5 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZNF250 | c.1379T>C p.F460S | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF578 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF611 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF729 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 89/317 reads (28%) | called by muse, varscan2
- ZNHIT1 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ABCA12 | c.267A>T p.P89= | Silent (SNP) | VAF 134/361 reads (37%) | called by muse, mutect2, varscan2
- ABCB4 | c.1146G>A p.E382= | Silent (SNP) | VAF 57/422 reads (14%) | catalogued as COSV55933595, COSV55939916; called by muse, mutect2, varscan2
- ABCG5 | c.354G>A p.R118= | Silent (SNP) | VAF 95/614 reads (15%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1296G>T p.L432= | Silent (SNP) | VAF 89/227 reads (39%) | catalogued as COSV51842990; called by muse, mutect2, varscan2
- ACTN2 | c.558C>A p.L186= | Silent (SNP) | VAF 159/518 reads (31%) | catalogued as COSV63972206; called by muse, mutect2, varscan2
- ADGRL2 | c.4089A>G p.L1363= (on ENST00000370717 / NM_001366005.1; = p.L1307= on NM_012302.4) | Silent (SNP) | VAF 45/233 reads (19%) | catalogued as rs1249480669, COSV54652710, COSV54663856; called by muse, mutect2, varscan2
- AHDC1 | c.1191G>C p.R397= | Silent (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- ALLC | c.1090C>A p.R364= | Silent (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- BFSP1 | c.888G>A p.A296= | Silent (SNP) | VAF 77/368 reads (21%) | catalogued as rs749513994, COSV100925375; called by muse, mutect2, varscan2
- BSN | c.11076G>T p.P3692= | Silent (SNP) | VAF 95/277 reads (34%) | called by muse, mutect2, varscan2
- C9 | c.1263C>G p.L421= | Silent (SNP) | VAF 38/361 reads (11%) | catalogued as COSV54675680; called by muse, mutect2, varscan2
- CA8 | c.303A>T p.G101= | Silent (SNP) | VAF 74/197 reads (38%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.769C>T p.L257= | Silent (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- CASR | c.2733C>A p.A911= (on ENST00000490131; = p.A988= on NM_000388.4) | Silent (SNP) | VAF 119/644 reads (18%) | called by muse, mutect2, varscan2
- CFAP97D1 | c.96C>T p.Y32= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs777725073; called by muse, mutect2, varscan2
- COL7A1 | c.2958C>A p.I986= | Silent (SNP) | VAF 147/481 reads (31%) | catalogued as COSV60396132; called by muse, mutect2, varscan2
- COP1 | c.1413G>A p.S471= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs775362186; called by muse, mutect2, varscan2
- COQ6 | c.1185G>A p.T395= | Silent (SNP) | VAF 60/421 reads (14%) | catalogued as rs148593471; ClinVar: likely benign; called by muse, mutect2, varscan2
- CROCC2 | c.1413C>A p.A471= | Silent (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- CUTC | c.123A>T p.A41= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- CYP4F12 | c.456G>T p.T152= | Silent (SNP) | VAF 93/437 reads (21%) | called by muse, mutect2, varscan2
- DDX52 | c.18C>T p.L6= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs145024282; called by muse, mutect2, varscan2
- DEFA3 | c.42C>A p.A14= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- EGFLAM | c.1443G>C p.L481= | Silent (SNP) | VAF 75/392 reads (19%) | called by muse, mutect2, varscan2
- EGFR | c.1533C>T p.S511= | Silent (SNP) | VAF 73/271 reads (27%) | called by muse, mutect2, varscan2
- FAM111B | c.789C>G p.V263= | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- FAM135B | c.724C>A p.R242= | Silent (SNP) | VAF 30/228 reads (13%) | catalogued as COSV52752592; called by muse, mutect2, varscan2
- FBXO40 | c.279C>T p.V93= | Silent (SNP) | VAF 58/402 reads (14%) | called by muse, mutect2
- FOXA3 | c.336C>A p.P112= | Silent (SNP) | VAF 130/310 reads (42%) | called by muse, mutect2, varscan2
- FOXL1 | c.456G>A p.P152= | Silent (SNP) | VAF 63/325 reads (19%) | called by muse, mutect2, varscan2
- FPGS | c.1266G>T p.A422= | Silent (SNP) | VAF 150/370 reads (41%) | catalogued as rs573086299; called by muse, mutect2, varscan2
- GABRQ | c.1287G>T p.S429= | Silent (SNP) | VAF 118/222 reads (53%) | catalogued as COSV64782575; called by muse, mutect2, varscan2
- GALR1 | c.231G>T p.L77= | Silent (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- GNA12 | c.1131C>T p.D377= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs759492536; called by muse, varscan2
- GOLGA4 | c.2799C>A p.A933= | Silent (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- GPR89B | c.369C>T p.F123= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs587766922; called by mutect2, varscan2
- GSE1 | c.2007C>T p.P669= | Silent (SNP) | VAF 48/239 reads (20%) | catalogued as rs775473962, COSV99497226; called by muse, mutect2, varscan2
- GSX2 | c.219G>T p.R73= | Silent (SNP) | VAF 96/538 reads (18%) | called by muse, mutect2, varscan2
- HNF4G | c.321G>T p.L107= (on ENST00000354370 / NM_001330561.2; = p.L154= on NM_004133.5) | Silent (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- HNF4G | c.441C>T p.L147= (on ENST00000354370 / NM_001330561.2; = p.L194= on NM_004133.5) | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- HYAL4 | c.1377C>T p.S459= | Silent (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- IGFN1 | c.2982G>T p.V994= (on ENST00000295591 / NM_001367841.1; = p.V3451= on NM_001164586.2) | Silent (SNP) | VAF 84/260 reads (32%) | called by muse, mutect2, varscan2
- ITGAX | c.993G>A p.E331= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- KAT6A | c.2352T>A p.S784= | Silent (SNP) | VAF 91/496 reads (18%) | called by muse, mutect2, varscan2
- KCNB2 | c.1347C>T p.I449= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as rs781521472, COSV101578684, COSV101579115; called by muse, mutect2, varscan2
- KCTD13 | c.801C>T p.L267= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as rs754862137, COSV58157958; called by muse, mutect2
- KCTD3 | c.714G>T p.V238= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2904G>A p.Q968= (on ENST00000321505; = p.Q1265= on NM_012194.3) | Silent (SNP) | VAF 91/236 reads (39%) | called by muse, mutect2, varscan2
- KLHL30 | c.273G>T p.V91= | Silent (SNP) | VAF 55/367 reads (15%) | catalogued as rs754315719; called by muse, mutect2, varscan2
- KRTAP4-2 | c.204C>A p.T68= | Silent (SNP) | VAF 176/490 reads (36%) | called by muse, mutect2, varscan2
- LCE1A | c.186T>C p.S62= | Silent (SNP) | VAF 82/508 reads (16%) | called by muse, mutect2, varscan2
- LOXL1 | c.621C>G p.P207= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- LRP1 | c.3495G>T p.L1165= | Silent (SNP) | VAF 110/621 reads (18%) | called by muse, mutect2, varscan2
- MAGI2 | c.1243C>A p.R415= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- MAMLD1 | c.54C>T p.A18= | Silent (SNP) | VAF 65/117 reads (56%) | catalogued as COSV99476551; called by muse, mutect2, varscan2
- MAS1L | c.471T>C p.F157= | Silent (SNP) | VAF 94/302 reads (31%) | called by muse, varscan2
- MAS1L | c.426G>A p.V142= | Silent (SNP) | VAF 44/208 reads (21%) | catalogued as rs1475436376; called by muse, varscan2
- MBTPS1 | c.2307C>T p.F769= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs1490143851; called by muse, mutect2, varscan2
- MDGA2 | c.526C>A p.R176= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs1021338953; called by muse, mutect2, varscan2
- MGAT4A | c.1101A>G p.S367= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- MMAB | c.309C>T p.V103= | Silent (SNP) | VAF 26/624 reads (4%) | called by muse, mutect2
- MROH2A | c.2076C>A p.G692= | Silent (SNP) | VAF 80/232 reads (34%) | called by muse, varscan2
- MUC3A | c.7785A>T p.A2595= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1158938213; called by muse, mutect2, varscan2
- NEGR1 | c.630A>C p.S210= | Silent (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- NEMF | c.1065A>G p.L355= | Silent (SNP) | VAF 61/344 reads (18%) | catalogued as rs1188452944, COSV104403597; called by muse, mutect2, varscan2
- NEURL2 | c.579C>A p.L193= | Silent (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- NOTCH2 | c.3396G>T p.T1132= | Silent (SNP) | VAF 130/395 reads (33%) | catalogued as rs140630687, COSV56706657; called by muse, mutect2, varscan2
- NPIPB4 | c.781C>T p.L261= | Silent (SNP) | VAF 167/1033 reads (16%) | called by muse, mutect2, varscan2
- NUP210L | c.1227A>G p.E409= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- OBSCN | c.9804A>T p.T3268= | Silent (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- OR51I2 | c.657G>A p.V219= | Silent (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2, varscan2
- OTUD7A | c.304C>T p.L102= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as rs764562285; called by muse, mutect2, varscan2
- PACS2 | c.1218G>A p.P406= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as rs782790557; called by muse, mutect2, varscan2
- PAFAH1B3 | c.622C>T p.L208= | Silent (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- PAK5 | c.729C>T p.S243= | Silent (SNP) | VAF 59/301 reads (20%) | catalogued as rs531425529, COSV62028487; called by muse, mutect2, varscan2
- PAXIP1 | c.2097C>T p.F699= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as COSV68187288; called by muse, mutect2, varscan2
- PCDH17 | c.3126G>T p.A1042= | Silent (SNP) | VAF 63/183 reads (34%) | catalogued as COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2, varscan2
- PCDHGC5 | c.219C>T p.R73= | Silent (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- PDE3B | c.1578T>A p.T526= | Silent (SNP) | VAF 136/297 reads (46%) | called by muse, mutect2, varscan2
- PDSS2 | c.891C>T p.V297= | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, varscan2
- PEG3 | c.1944C>T p.I648= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99688021; called by muse, mutect2, varscan2
- PGPEP1L | c.453G>A p.S151= | Silent (SNP) | VAF 87/515 reads (17%) | catalogued as rs747165092, COSV51324930; called by muse, mutect2, varscan2
- PHACTR3 | c.849G>T p.T283= | Silent (SNP) | VAF 58/290 reads (20%) | catalogued as rs369078709; called by muse, mutect2, varscan2
- PKD1L1 | c.7377C>T p.L2459= | Silent (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- PLEKHS1 | c.1095G>T p.L365= | Silent (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- POGZ | c.3324A>T p.V1108= | Silent (SNP) | VAF 63/194 reads (32%) | catalogued as COSV99304959; called by muse, mutect2, varscan2
- POTEG | c.999T>A p.S333= | Silent (SNP) | VAF 57/673 reads (8%) | called by muse, varscan2
- PRAM1 | c.1920C>A p.P640= | Silent (SNP) | VAF 84/334 reads (25%) | called by muse, mutect2, varscan2
- PRB1 | c.262C>A p.R88= | Silent (SNP) | VAF 69/307 reads (22%) | catalogued as rs764285677, COSV53707368; called by muse, mutect2, varscan2
- PRSS21 | c.12C>A p.R4= | Silent (SNP) | VAF 74/396 reads (19%) | called by muse, mutect2, varscan2
- PTPN6 | c.534G>T p.V178= | Silent (SNP) | VAF 245/580 reads (42%) | catalogued as rs1555148375; called by muse, mutect2, varscan2
- PYGB | c.2241C>T p.S747= | Silent (SNP) | VAF 104/562 reads (19%) | catalogued as COSV53823091; called by muse, varscan2
- REN | c.27C>T p.R9= | Silent (SNP) | VAF 83/546 reads (15%) | called by muse, mutect2, varscan2
- RNF113B | c.654C>T p.S218= | Silent (SNP) | VAF 124/384 reads (32%) | called by mutect2, varscan2
- RNF123 | c.1029G>C p.L343= | Silent (SNP) | VAF 41/331 reads (12%) | catalogued as rs1208559765; called by muse, mutect2, varscan2
- RP1L1 | c.2232C>A p.V744= | Silent (SNP) | VAF 59/256 reads (23%) | called by muse, mutect2, varscan2
- RPL39 | c.147G>T p.L49= | Silent (SNP) | VAF 44/76 reads (58%) | called by muse, mutect2, varscan2
- RYR2 | c.12414C>A p.I4138= | Silent (SNP) | VAF 60/192 reads (31%) | called by muse, mutect2, varscan2
- RYR3 | c.13125G>T p.R4375= (on ENST00000389232; = p.R4376= on NM_001036.6) | Silent (SNP) | VAF 35/257 reads (14%) | called by muse, mutect2, varscan2
- SELENOV | c.951C>T p.V317= | Silent (SNP) | VAF 151/404 reads (37%) | catalogued as COSV59064037; called by muse, mutect2, varscan2
- SGCA | c.1134C>A p.A378= | Silent (SNP) | VAF 170/922 reads (18%) | called by muse, mutect2, varscan2
- SIM2 | c.1455C>A p.A485= | Silent (SNP) | VAF 59/256 reads (23%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1527G>T p.V509= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2
- SLC2A5 | c.1458G>A p.P486= | Silent (SNP) | VAF 43/294 reads (15%) | catalogued as rs750455456, COSV66236540; called by muse, mutect2, varscan2
- SLC30A10 | c.912C>T p.A304= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as rs1160605661; called by muse, mutect2, varscan2
- SLC39A12 | c.783C>A p.T261= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV101070246; called by muse, mutect2, varscan2
- SLC8A1 | c.876C>T p.D292= | Silent (SNP) | VAF 104/265 reads (39%) | catalogued as rs201010344; called by muse, mutect2, varscan2
- SMAP2 | c.1194C>T p.F398= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs1484192615; called by muse, mutect2, varscan2
- SMUG1 | c.237A>T p.V79= | Silent (SNP) | VAF 46/206 reads (22%) | called by muse, mutect2, varscan2
- SPATA31A7 | c.270C>A p.G90= | Silent (SNP) | VAF 115/675 reads (17%) | called by muse, mutect2, varscan2
- SPOCK2 | c.1200G>A p.T400= | Silent (SNP) | VAF 108/240 reads (45%) | catalogued as rs533844555, COSV58038235; called by muse, mutect2, varscan2
- SYCP2 | c.1746G>A p.Q582= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- SYN2 | c.720A>T p.G240= | Silent (SNP) | VAF 33/237 reads (14%) | called by muse, mutect2, varscan2
- TAPT1 | c.705C>T p.H235= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- TBX5 | c.1377C>T p.T459= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as rs913297012, COSV59861475; called by muse, mutect2, varscan2
- TCHH | c.5439C>A p.R1813= | Silent (SNP) | VAF 66/358 reads (18%) | called by muse, mutect2, varscan2
- TEKT4 | c.1191C>T p.H397= | Silent (SNP) | VAF 151/486 reads (31%) | catalogued as rs1261007246; called by muse, mutect2, varscan2
- TMEFF1 | c.156G>T p.G52= | Silent (SNP) | VAF 92/232 reads (40%) | called by muse, mutect2, varscan2
- TMEM132D | c.1314G>A p.L438= | Silent (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- TMEM217 | c.639A>T p.P213= | Silent (SNP) | VAF 81/252 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.80199C>A p.V26733= (on ENST00000591111; = p.V19309= on NM_003319.4) | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs1278975769, COSV59904820; called by muse, mutect2, varscan2
- UBE2D4 | c.21G>A p.Q7= | Silent (SNP) | VAF 73/259 reads (28%) | catalogued as rs1036144185; called by muse, mutect2, varscan2
- UNC13D | c.1455G>A p.P485= | Silent (SNP) | VAF 86/492 reads (17%) | catalogued as rs370940775, COSV99257260; called by muse, mutect2, varscan2
- WDR45B | c.708C>T p.I236= | Silent (SNP) | VAF 82/551 reads (15%) | catalogued as rs756853385, COSV66407756; called by muse, mutect2, varscan2
- XIRP2 | c.8352G>T p.S2784= (on ENST00000628543; = p.S2959= on NM_152381.6) | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV99738679; called by muse, mutect2, varscan2
- ZNF195 | c.1407A>G p.E469= (on ENST00000399602 / NM_001130520.3; = p.E397= on NM_007152.5) | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs377229792; called by muse, mutect2, varscan2
- ZNF423 | c.1752C>A p.S584= (on ENST00000563137 / NM_001379286.1; = p.S576= on NM_015069.4) | Silent (SNP) | VAF 65/208 reads (31%) | called by muse, mutect2, varscan2
- AC005670.2 | chr17:47049763 C>G | 3'Flank (SNP) | VAF 23/761 reads (3%) | called by muse, mutect2
- ALG10B | c.*2683A>C | 3'UTR (SNP) | VAF 23/157 reads (15%) | catalogued as rs1487370474; called by muse, mutect2, varscan2
- ALG2 | c.*926A>T | 3'UTR (SNP) | VAF 93/261 reads (36%) | called by muse, mutect2, varscan2
- ANKRD33 | c.-5-108C>A | Intron (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500981 G>C | 5'Flank (SNP) | VAF 40/213 reads (19%) | called by muse, mutect2, varscan2
- AUTS2 | c.2004+12C>T | Intron (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- BAIAP2 | c.280-179G>T | Intron (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2
- C20orf197 | n.506G>T | RNA (SNP) | VAF 83/358 reads (23%) | called by muse, mutect2, varscan2
- C5orf17 | n.407G>T | RNA (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CASC15 | chr6:22146743 G>A | 5'Flank (SNP) | VAF 33/259 reads (13%) | catalogued as rs1221142335; called by muse, mutect2, varscan2
- CC2D1A | c.1357-33G>T | Intron (SNP) | VAF 167/482 reads (35%) | called by muse, mutect2, varscan2
- CCDC198 | c.656-4022G>A | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- CDH11 | c.-347G>A | 5'UTR (SNP) | VAF 83/574 reads (14%) | called by muse, mutect2, varscan2
- CEP164 | c.393+3130C>T | Intron (SNP) | VAF 94/210 reads (45%) | called by muse, mutect2, varscan2
- CHCHD2 | c.-57C>T | 5'UTR (SNP) | VAF 43/308 reads (14%) | catalogued as COSV101271049; called by muse, mutect2, varscan2
- CLUL1 | c.*48C>G | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- CTCFL | c.1674+821G>T | Intron (SNP) | VAF 91/470 reads (19%) | called by muse, mutect2, varscan2
- CYP2A7P1 | n.267G>C | RNA (SNP) | VAF 96/319 reads (30%) | catalogued as rs771456919; called by muse, varscan2
- DBF4B | c.1189+387G>C | Intron (SNP) | VAF 49/226 reads (22%) | called by muse, mutect2, varscan2
- DNM1P34 | n.587C>T | RNA (SNP) | VAF 34/258 reads (13%) | catalogued as rs754808569; called by muse, varscan2
- EDA | c.397-96140C>G | Intron (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- EIF4H | c.469+968C>T | Intron (SNP) | VAF 31/108 reads (29%) | catalogued as rs782446761; called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2671C>T | Intron (SNP) | VAF 97/424 reads (23%) | catalogued as rs898339565; called by muse, mutect2, varscan2
- FAM126A | c.-202C>G | 5'UTR (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-752C>A | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- GREB1 | c.1346-1375C>G | Intron (SNP) | VAF 81/267 reads (30%) | catalogued as rs375397931; called by muse, mutect2, varscan2
- GRIA3 | c.268+18467del | Intron (DEL) | VAF 87/194 reads (45%) | catalogued as COSV99054877; called by mutect2, pindel, varscan2
- GUCY2EP | n.1417A>G | RNA (SNP) | VAF 40/259 reads (15%) | catalogued as rs1224390111; called by muse, mutect2, varscan2
- HHLA3 | n.398-135G>T | Intron (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.98-575G>T | Intron (SNP) | VAF 64/214 reads (30%) | called by muse, mutect2, varscan2
- HRG | c.-16G>T | 5'UTR (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.-11C>A | 5'UTR (SNP) | VAF 32/224 reads (14%) | catalogued as rs1473568782; called by muse, mutect2, varscan2
- IL17RD | chr3:57169244 G>C | 5'Flank (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- IL2RB | c.204-117C>A | Intron (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- IMMP2L | c.*34del | 3'UTR (DEL) | VAF 96/390 reads (25%) | called by mutect2, pindel, varscan2
- LAX1 | c.-224G>C | 5'UTR (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- LDAH | c.298+1076G>T | Intron (SNP) | VAF 49/427 reads (11%) | called by muse, mutect2, varscan2
- LINC01630 | n.1172G>T | RNA (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- LRP5 | c.*17C>G | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- LRRC8C | c.139-6341C>T | Intron (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- LUC7L2 | c.-38C>T | 5'UTR (SNP) | VAF 24/158 reads (15%) | catalogued as rs929287063; called by muse, mutect2, varscan2
- MASP1 | c.1304-5754G>T | Intron (SNP) | VAF 52/664 reads (8%) | catalogued as COSV99961770; called by muse, mutect2
- MIR133A2 | chr20:62565030 G>C | 3'Flank (SNP) | VAF 63/307 reads (21%) | called by muse, mutect2, varscan2
- MIR513C | n.53T>G | RNA (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- NAV3 | c.6519-205_6519-204del | Intron (DEL) | VAF 19/121 reads (16%) | called by mutect2, pindel, varscan2
- NBAS | c.6712-10G>T | Intron (SNP) | VAF 49/422 reads (12%) | catalogued as rs967704371; called by muse, mutect2, varscan2
- NDUFAF5 | c.*293T>A | 3'UTR (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- NEK8 | c.828-34G>T | Intron (SNP) | VAF 163/399 reads (41%) | called by muse, mutect2, varscan2
- NEURL1 | c.86-15503C>T | Intron (SNP) | VAF 50/151 reads (33%) | catalogued as rs760290483; called by muse, mutect2, varscan2
- NRIP1 | c.-537-7299G>A | Intron (SNP) | VAF 50/327 reads (15%) | called by muse, mutect2, varscan2
- PHACTR1 | c.251-119605C>A | Intron (SNP) | VAF 59/450 reads (13%) | catalogued as rs1279425940; called by muse, mutect2, varscan2
- PKD1 | c.9568+32C>G | Intron (SNP) | VAF 216/784 reads (28%) | catalogued as rs1382476460; called by muse, mutect2, varscan2
- PLD1 | c.2429+4994G>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.992G>T | RNA (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.-89G>T | 5'UTR (SNP) | VAF 113/240 reads (47%) | called by muse, mutect2, varscan2
- PPFIA4 | c.-429C>A | 5'UTR (SNP) | VAF 52/388 reads (13%) | called by muse, mutect2, varscan2
- PPP2R2B | c.1052+905T>C | Intron (SNP) | VAF 52/138 reads (38%) | called by muse, mutect2, varscan2
- PSMA1 | c.-29G>C | 5'UTR (SNP) | VAF 106/247 reads (43%) | catalogued as rs566878004; called by muse, mutect2, varscan2
- RAB18 | c.*2591G>T | 3'UTR (SNP) | VAF 139/355 reads (39%) | called by muse, mutect2, varscan2
- RBP4 | c.*24C>G | 3'UTR (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- RESF1 | c.5003-56G>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- RFX7 | c.-21G>A | 5'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559049 G>T | 5'Flank (SNP) | VAF 62/624 reads (10%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.147C>A | RNA (SNP) | VAF 87/728 reads (12%) | called by muse, mutect2, varscan2
- RTN4R | c.23-480C>T | Intron (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- SATB2 | c.*4G>A | 3'UTR (SNP) | VAF 49/456 reads (11%) | called by muse, mutect2, varscan2
- SCAF8 | c.-388G>C | 5'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, varscan2
- SLC29A2 | c.1260-70G>A | Intron (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2
- SNORD116-17 | chr15:25088417 G>T | 3'Flank (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SNURFL | n.66G>A | RNA (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SPANXN1 | c.-39C>A | 5'UTR (SNP) | VAF 14/207 reads (7%) | called by muse, mutect2
- SSTR5-AS1 | n.1068C>A | RNA (SNP) | VAF 68/446 reads (15%) | called by muse, mutect2
- SSX9P | n.282C>A | RNA (SNP) | VAF 112/211 reads (53%) | called by muse, mutect2, varscan2
- STIM2 | c.1764-1548C>T | Intron (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- SYT14 | c.*303C>A | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- TMEM135 | c.*1647G>T | 3'UTR (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- TMEM135 | c.*5985C>A | 3'UTR (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- TMEM135 | c.*6967C>G | 3'UTR (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- TMEM167B | chr1:109100560 G>A | 3'Flank (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- TMEM99 | n.398A>G | RNA (SNP) | VAF 45/180 reads (25%) | catalogued as rs778571392; called by muse, mutect2, varscan2
- TNS1 | c.-25G>A | 5'UTR (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- TPM1 | c.114+515T>A | Intron (SNP) | VAF 58/335 reads (17%) | called by muse, mutect2, varscan2
- TRIM51BP | n.1184C>A | RNA (SNP) | VAF 34/168 reads (20%) | called by mutect2, varscan2
- TSPO | c.*7G>T | 3'UTR (SNP) | VAF 56/351 reads (16%) | called by muse, mutect2, varscan2
- UBBP4 | n.784C>G | RNA (SNP) | VAF 255/1263 reads (20%) | called by muse, varscan2
- UBD | c.-20C>G | 5'UTR (SNP) | VAF 26/171 reads (15%) | catalogued as COSV63541039; called by muse, mutect2, varscan2
- UQCRB | c.*1843C>T | 3'UTR (SNP) | VAF 41/377 reads (11%) | called by muse, mutect2, varscan2
- XIST | n.10352del | RNA (DEL) | VAF 86/193 reads (45%) | called by mutect2, pindel, varscan2
- ZNF57 | c.-62C>T | 5'UTR (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
